Somatic mutation profile of tumor specimen TCGA-AJ-A3TW-01A (aliquot TCGA-AJ-A3TW-01A-11D-A228-09) from TCGA case TCGA-AJ-A3TW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 78.2 years (28,559 days).
Specimen TCGA-AJ-A3TW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2258b748-1a17-4b95-a513-d04d74533610.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3TW-10A (Blood Derived Normal), aliquot TCGA-AJ-A3TW-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcc7328d-7af3-4f9e-a092-aac88cf70ba3

The open-access MAF lists 136 somatic variants for this specimen: 97 protein-altering or splice-affecting, 37 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 37, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 3, In Frame Del 1, Splice Region 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 53/66 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV99400266; called by muse, mutect2, varscan2
- ACTR1A | c.813G>C p.E271D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV100883733; called by muse, mutect2, varscan2
- AGAP2 | c.1318G>A p.E440K (on ENST00000547588 / NM_001122772.2; = p.E104K on NM_014770.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV99224163; called by muse, mutect2, varscan2
- AP4S1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99364386; called by muse, mutect2
- APOOL | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100920937; called by muse, mutect2, varscan2
- ATAD2 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV54878712; called by muse, mutect2, varscan2
- ATP8B1 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758353144, CM117172, COSV52180194; called by muse, mutect2, varscan2
- CAPN10 | c.998-1G>C p.X333_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99550523; called by muse, mutect2, varscan2
- CATSPER2 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.72); catalogued as COSV100390972; called by muse, mutect2, varscan2
- CCDC73 | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV100068260, COSV58797113; called by muse, mutect2, varscan2
- CDH13 | c.1631del p.P544Hfs*29 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | catalogued as COSV99224023; called by mutect2, pindel, varscan2
- CDH7 | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100543135, COSV59886195; called by muse, varscan2
- CDK4 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99225825, COSV99226116; called by muse, mutect2, varscan2
- CEBPZ | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99135768; called by muse, mutect2, varscan2
- CHEK2 | c.1355A>G p.D452G (on ENST00000382580 / NM_001005735.2; = p.D409G on NM_007194.4) | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100102414; called by muse, mutect2, varscan2
- CLUL1 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs753466551, COSV100621034, COSV58111541, COSV58111821; called by muse, mutect2, varscan2
- CNGB3 | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100182976; called by muse, mutect2
- CNTNAP2 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as rs1395023503, COSV100671414; called by muse, mutect2, varscan2
- CSDE1 | c.451C>T p.Q151* (on ENST00000358528 / NM_001007553.3; = p.Q120* on NM_007158.6) | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99795909; called by muse, mutect2, varscan2
- CSMD2 | c.6442G>A p.E2148K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV99594704; called by muse, mutect2, varscan2
- CWF19L2 | c.1107G>C p.L369F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV99979781; called by muse, mutect2, varscan2
- CYFIP1 | c.3347A>G p.N1116S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV100488738; called by muse, mutect2, varscan2
- CYP2C9 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as CM1412019, COSV99582741, COSV99583152; called by muse, mutect2, varscan2
- CYP2E1 | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV53315563, COSV99429185; called by muse, mutect2, varscan2
- DMXL1 | c.6586A>C p.N2196H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100224886; called by muse, mutect2, varscan2
- DNAH1 | c.12097C>T p.R4033W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs371210477, COSV99964438; called by muse, mutect2, varscan2
- DYRK1A | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100118263; called by muse, mutect2, varscan2
- FAM193A | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as rs1403030362, COSV99048799; called by muse, mutect2
- FANCA | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV101224851; called by muse, mutect2, varscan2
- FBL | c.462G>C p.Q154H | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99695414; called by muse, mutect2, varscan2
- FMO1 | c.777G>C p.K259N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV100707720, COSV100707914; called by muse, mutect2, varscan2
- FOXA2 | c.479C>T p.P160L (on ENST00000377115 / NM_153675.3; = p.P166L on NM_021784.5) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101008480; called by muse, mutect2, varscan2
- G6PC2 | c.235C>G p.R79G | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99960884; called by muse, mutect2, varscan2
- GPATCH2 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.778); catalogued as rs1416426877, COSV100861425; called by muse, mutect2, varscan2
- GTF2H5 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.12); catalogued as rs114381286, COSV101659576; called by muse, mutect2, varscan2
- H4C7 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV99769253; called by muse, varscan2
- IGHMBP2 | c.1650G>C p.Q550H | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV99662516; called by muse, mutect2, varscan2
- IGHV3-23 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.19); catalogued as rs528691476; called by muse, mutect2, varscan2
- IPO13 | c.2207G>C p.S736T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100960942; called by muse, mutect2, varscan2
- KIF20B | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53307621; called by muse, varscan2
- KMT2C | c.12645A>C p.K4215N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100076055; called by muse, mutect2, varscan2
- KNTC1 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1217968446, COSV100338746; called by muse, mutect2, varscan2
- KRT37 | c.575+1G>A p.X192_splice | Splice Site (SNP) | VAF 15/26 reads (58%) | catalogued as COSV99845690; called by muse, mutect2, varscan2
- MED30 | c.453G>C p.Q151H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.477); catalogued as COSV99816122; called by muse, mutect2, varscan2
- MEFV | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1206762845, COSV54824487, COSV54825840; called by muse, mutect2
- MEOX2 | c.470C>A p.A157E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.052); catalogued as rs1421793823, COSV100012491, COSV56287804; called by muse, mutect2, varscan2
- MIS18BP1 | c.1739C>T p.S580F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.124); catalogued as rs778474485, COSV100173235; called by muse, mutect2, varscan2
- MKRN3 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs926432888, COSV58810109; called by muse, mutect2, varscan2
- MPV17L2 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV99718103; called by muse, mutect2, varscan2
- MSH5 | c.1215G>A p.E405= | Splice Region (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100994974, COSV65209451; called by muse, mutect2, varscan2
- NLRC4 | c.2322G>C p.K774N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV100707508; called by muse, mutect2, varscan2
- NRBP1 | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51995093; called by muse, mutect2, varscan2
- NT5C2 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs745326714, COSV100583715; called by muse, mutect2, varscan2
- OR52K2 | c.551T>C p.M184T | Missense Mutation (SNP) | VAF 73/106 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs993359972, COSV100355837; called by muse, mutect2, varscan2
- OSBPL7 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99137001; called by muse, mutect2, varscan2
- PICALM | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1468771678, COSV100708211; called by muse, mutect2, varscan2
- PKD2 | c.2262G>C p.E754D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs1021224022, COSV52937339, COSV99417814; called by muse, mutect2, varscan2
- PLEKHA1 | c.828G>C p.E276D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.019); catalogued as COSV100935583; called by muse, mutect2, varscan2
- PLS1 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.097); catalogued as COSV100538314; called by muse, mutect2, varscan2
- PRAMEF20 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs763696662; called by muse, mutect2, varscan2
- PRKAR1B | c.187A>G p.R63G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100816837; called by muse, mutect2, varscan2
- PTPRD | c.3414A>T p.K1138N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV100646630; called by muse, mutect2, varscan2
- PXN | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as COSV99936270; called by muse, mutect2, varscan2
- RARB | c.528G>C p.E176D (on ENST00000383772 / NM_001290216.2; = p.E169D on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV100412830; called by muse, mutect2, varscan2
- RARG | c.910T>C p.F304L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as COSV100553661; called by muse, mutect2, varscan2
- RASA1 | c.2021G>C p.R674P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.372); catalogued as COSV57201432, COSV99170595; called by muse, mutect2, varscan2
- RYR1 | c.7708G>C p.A2570P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV100616836; called by muse, mutect2, varscan2
- SARS1 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as COSV99321530; called by muse, mutect2, varscan2
- SEMA4C | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs764755720, COSV100560716, COSV59691828; called by muse, mutect2
- SLC12A3 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99344676; called by muse, mutect2, varscan2
- SLC27A1 | c.1719G>C p.Q573H | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV99393620; called by muse, mutect2
- SLC7A13 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.482); catalogued as COSV52536722; called by muse, mutect2, varscan2
- SMCHD1 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99862469; called by muse, mutect2, varscan2
- SMCO3 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as rs1323221255, COSV99660857; called by muse, mutect2, varscan2
- SRBD1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV55400486; called by muse, mutect2, varscan2
- ST18 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 61/103 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99390910; called by muse, mutect2, varscan2
- STAB2 | c.5074G>A p.V1692I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as rs575022633, COSV101186270; called by muse, mutect2, varscan2
- TCEAL8 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100749840; called by muse, mutect2, varscan2
- THOC5 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100803650; called by muse, mutect2, varscan2
- TMEM100 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV101448240; called by muse, mutect2, varscan2
- TMEM94 | c.3221G>A p.S1074N | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100050879; called by muse, mutect2, varscan2
- TTN | c.33145G>A p.E11049K (on ENST00000591111; = p.E10122K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/121 reads (16%) | PolyPhen benign (0.025); catalogued as COSV100627752; called by muse, mutect2, varscan2
- UBAP1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99903553; called by muse, mutect2, varscan2
- UTP25 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV101530974; called by muse, mutect2, varscan2
- WDR17 | c.3805C>A p.H1269N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV99708193; called by muse, mutect2, varscan2
- XKRX | c.602G>C p.R201T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60707944, COSV60708121; called by muse, mutect2, varscan2
- ZBTB20 | c.680C>T p.T227M (on ENST00000474710 / NM_001164342.2; = p.T154M on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV61845502; called by muse, mutect2, varscan2
- ZNF165 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs768075242, COSV66102208, COSV66102924; called by muse, mutect2, varscan2
- ZNF300 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99200103; called by muse, mutect2, varscan2
- ZNF318 | c.950A>C p.E317A | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100546478; called by muse, mutect2
- ZNF420 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100421492; called by muse, mutect2, varscan2
- CCDC7 | c.1050del p.D351Tfs*20 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- EXOC1 | c.1953+3_1953+6del p.X651_splice | Splice Site (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- GPAT2 | c.2246_2248del p.A749del | In Frame Del (DEL) | VAF 16/40 reads (40%) | called by mutect2, pindel, varscan2
- SAMD9L | c.2921_2924del p.T974Kfs*17 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- ACTR1A | c.954G>T p.V318= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99488027; called by muse, mutect2, varscan2
- AP1M1 | c.393G>A p.L131= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV99358632; called by muse, mutect2
- BEST2 | c.111C>T p.L37= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV50375105, COSV99244644; called by muse, mutect2, varscan2
- CBX4 | c.366C>G p.L122= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs1226574348, COSV53965025; called by muse, mutect2, varscan2
- DLL3 | c.1839G>C p.S613= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as rs777658037, COSV99219447; called by muse, mutect2, varscan2
- DNAH2 | c.4908C>G p.L1636= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV101209568; called by muse, mutect2
- DPY19L3 | c.633G>A p.L211= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV60476384; called by muse, mutect2, varscan2
- FGF12 | c.75G>T p.S25= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53158392, COSV99283538; called by muse, mutect2, varscan2
- GHDC | c.486A>T p.R162= | Silent (SNP) | VAF 22/27 reads (81%) | catalogued as COSV100054932; called by muse, mutect2, varscan2
- GRIN3A | c.1971G>A p.V657= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100701780; called by muse, mutect2, varscan2
- HRNR | c.1269T>C p.S423= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV64262019; called by muse, mutect2
- IRX5 | c.312G>A p.A104= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100315969; called by muse, mutect2, varscan2
- ISLR2 | c.279C>T p.G93= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV62302063; called by muse, mutect2, varscan2
- JAKMIP2 | c.2277G>C p.L759= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99509159; called by muse, mutect2, varscan2
- JARID2 | c.1710G>A p.P570= | Silent (SNP) | VAF 31/51 reads (61%) | catalogued as rs749672209, COSV100522345; called by muse, mutect2, varscan2
- LILRB5 | c.1299C>A p.P433= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100300766; called by muse, mutect2, varscan2
- LPIN1 | c.1755G>A p.P585= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs772079983, COSV99878128; called by muse, mutect2, varscan2
- LRRC4 | c.201C>T p.S67= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs369440445, COSV99974777; called by muse, mutect2, varscan2
- MAP3K4 | c.4182C>T p.F1394= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs367694278; called by muse, mutect2, varscan2
- MYH7B | c.4848C>T p.V1616= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99328852; called by mutect2, varscan2
- PLEKHG4B | c.3183C>T p.V1061= (on ENST00000283426; = p.V1417= on NM_052909.5) | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs201699462, COSV99360970; called by muse, mutect2
- PPM1G | c.309C>A p.A103= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100641955; called by muse, mutect2, varscan2
- PRPF3 | c.765A>G p.P255= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100255073; called by muse, mutect2
- RBM34 | c.318G>A p.V106= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV64013237; called by muse, mutect2, varscan2
- RELA | c.519C>T p.L173= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs771027934, COSV100425930; called by muse, mutect2, varscan2
- RTN3 | c.1758C>T p.P586= (on ENST00000377819 / NM_001265589.2; = p.P567= on NM_201428.3) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs550199424, COSV100380330; called by muse, mutect2, varscan2
- SCARA5 | c.888C>A p.I296= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100108063; called by muse, mutect2, varscan2
- SDK1 | c.3618C>T p.P1206= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs375214216, COSV67375754; called by muse, mutect2, varscan2
- SKIV2L | c.1881C>T p.L627= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100952852; called by muse, mutect2, varscan2
- SNX30 | c.714G>A p.R238= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV100953960; called by muse, mutect2, varscan2
- SPTBN5 | c.4191G>C p.L1397= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100312105; called by muse, mutect2, varscan2
- SYNE2 | c.10281G>A p.L3427= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100648411; called by muse, mutect2, varscan2
- TAF4 | c.3189C>A p.L1063= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99434956; called by muse, mutect2, varscan2
- TAFA4 | c.57C>G p.L19= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99808037; called by muse, mutect2, varscan2
- TIAM1 | c.3786G>C p.L1262= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99733698, COSV99738508; called by muse, mutect2, varscan2
- TRIM48 | c.606C>A p.P202= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV101338351; called by muse, mutect2, varscan2
- TTN | c.24147G>A p.L8049= (on ENST00000591111; = p.L7122= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV59902084; called by muse, mutect2
- MIR518B | n.28G>A | RNA (SNP) | VAF 14/67 reads (21%) | catalogued as rs781412310; called by muse, mutect2, varscan2
- TTBK2 | c.823-7027C>T | Intron (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
